Somatic mutation profile of tumor specimen TCGA-HT-8105-01A (aliquot TCGA-HT-8105-01A-11D-2395-08) from TCGA case TCGA-HT-8105, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 54.9 years (20,041 days).
Specimen TCGA-HT-8105-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57d5ea0c-3757-47d7-a4dc-773c19ab6e7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8105-10A (Blood Derived Normal), aliquot TCGA-HT-8105-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e34e8b7-1839-4026-b9a0-02bffcf151f1

The open-access MAF lists 48 somatic variants for this specimen: 41 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 22, Frame Shift Del 8, Silent 7, In Frame Del 6, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NAGLU | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs555145190, CM053338, COSV56795748; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs560787141, COSV100879356, COSV66105839; called by muse, mutect2, varscan2
- ABCC9 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs772244404, COSV53979000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGAP3 | c.2552C>T p.A851V (on ENST00000622464; = p.A887V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as rs773956176, COSV52547641, COSV52548615; called by muse, mutect2, varscan2
- ARMC9 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV63022308, COSV63022800; called by muse, mutect2, varscan2
- C1orf131 | c.149_151del p.K50del | In Frame Del (DEL) | VAF 9/68 reads (13%) | catalogued as rs754299558; called by pindel, varscan2
- CAPS2 | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs777930739, COSV60824017; called by muse, mutect2, varscan2
- CNTN2 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.145); catalogued as COSV59352007; called by muse, mutect2
- CRLF2 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67493573; called by muse, mutect2, varscan2
- DDX51 | c.996-2A>G p.X332_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV57959461; called by muse, mutect2, varscan2
- EFTUD2 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV68184244; called by muse, mutect2, varscan2
- GOLGA4 | c.6685A>G p.I2229V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.437); catalogued as COSV62712765; called by muse, varscan2
- GRM7 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371496119, COSV63159973; called by muse, mutect2, varscan2
- HEY1 | c.736_738del p.S246del | In Frame Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs1410300942; called by mutect2, varscan2
- KCNG4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.99); catalogued as rs750331316, COSV57585376; called by muse, varscan2
- KCNG4 | c.337_339del p.F113del | In Frame Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs774697136; called by pindel, varscan2
- LAMA2 | c.6201_6203del p.K2067del | In Frame Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs758495000; called by pindel, varscan2
- MYH11 | c.3818G>A p.R1273Q | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1473608237, COSV55564101; called by muse, mutect2, varscan2
- NYAP2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs551352616, COSV55999744; called by muse, mutect2, varscan2
- OR5H14 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 86/127 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs370923244; called by muse, varscan2
- RPL23 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); catalogued as COSV55560422; called by muse, mutect2, varscan2
- RSF1 | c.3347A>G p.Q1116R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV57843885; called by muse, mutect2, varscan2
- SCYL3 | c.438_441del p.C147Kfs*10 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs1283610806; called by mutect2, pindel, varscan2
- SETX | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV56391616; called by muse, mutect2, varscan2
- SIM1 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189500818, COSV53495071; called by muse, mutect2, varscan2
- SLC6A3 | c.1417A>C p.T473P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV54367815; called by muse, varscan2
- TCF12 | c.515_516del p.S172Cfs*4 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs1352309780; called by pindel, varscan2
- ZER1 | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV52567758; called by muse, mutect2, varscan2
- ZNF521 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64128383; called by muse, mutect2
- BCOR | c.3005_3008dup p.Q1004Ifs*15 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- C1GALT1 | c.443_446del p.I148Kfs*11 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- CELSR3 | c.703dup p.L235Pfs*69 | Frame Shift Ins (INS) | VAF 59/189 reads (31%) | called by mutect2, pindel, varscan2
- CIC | c.1990_1991del p.L664Vfs*25 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | called by mutect2, pindel, varscan2
- CREB3 | c.1054_1057del p.K352Efs*66 | Frame Shift Del (DEL) | VAF 60/266 reads (23%) | called by pindel, varscan2
- FUBP1 | c.1328_1329del p.I443Rfs*47 | Frame Shift Del (DEL) | VAF 26/40 reads (65%) | called by mutect2, pindel, varscan2
- KAT6B | c.3606_3609del p.T1203Rfs*21 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- MEGF9 | c.1001_1003del p.E334del | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2
- NOTCH1 | c.1117_1119del p.N373del | In Frame Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- PLEKHB1 | c.293_294del p.V98Efs*17 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by pindel, varscan2
- CCDC33 | c.1539G>A p.L513= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV51502305; called by muse, mutect2, varscan2
- CNGB1 | c.3543C>T p.T1181= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs375919369; called by muse, mutect2, varscan2
- GFRA2 | c.144C>T p.A48= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1246721284; called by muse, mutect2, varscan2
- H1-2 | c.27C>G p.P9= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV59190085, COSV59191897; called by muse, mutect2, varscan2
- PLCH1 | c.3813G>A p.T1271= (on ENST00000340059 / NM_001130960.2; = p.T1263= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as rs766465810, COSV58190024; called by muse, mutect2, varscan2
- SIRPD | c.504G>A p.S168= | Silent (SNP) | VAF 62/172 reads (36%) | catalogued as rs746018787, COSV67547077; called by muse, mutect2, varscan2
- SLITRK5 | c.1857A>G p.V619= | Silent (SNP) | VAF 20/247 reads (8%) | catalogued as COSV61524975; called by muse, mutect2
